Somatic mutation profile of tumor specimen MBCProject_4589_T1_WES (aliquot MBCProject_4589_T1_WES_1) from CMI case MBCProject_4589, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 70.4 years (25,721 days).
Specimen MBCProject_4589_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ee7164a-4842-4728-a096-afd51173773b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4589_SALIVA (Saliva), aliquot MBCProject_4589_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdc29967-26e5-4edf-a894-96f525ed3685

The open-access MAF lists 84 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, RNA 4, Intron 4, Nonsense Mutation 4, 3'UTR 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 36/119 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs977492722, COSV52643826; called by muse, mutect2, varscan2
- ACOXL | c.1362T>G p.I454M (on ENST00000389811 / NM_001371254.1; = p.I424M on NM_001142807.4) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV101096115; called by muse, mutect2, varscan2
- AFF2 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as COSV60665751; called by muse, mutect2
- C1orf116 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs1358311003; called by muse, mutect2
- CNNM2 | c.274dup p.A92Gfs*21 | Frame Shift Ins (INS) | VAF 30/126 reads (24%) | catalogued as rs768722573; called by mutect2, varscan2
- CNTRL | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV53052086, COSV53053515; called by muse, mutect2, varscan2
- DRGX | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770302415, COSV100938426; called by muse, mutect2
- GRB2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs1487234599, COSV57307677; called by muse, mutect2, varscan2
- HTT | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61865612; called by muse, mutect2, varscan2
- LGALS3BP | c.52+1G>A p.X18_splice | Splice Site (SNP) | VAF 15/139 reads (11%) | catalogued as rs747685151; called by muse, mutect2, varscan2
- LRFN3 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as rs750754362, COSV55817093; called by muse, mutect2, varscan2
- LRRC70 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1439025161; called by muse, mutect2, varscan2
- MED14 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100247283; called by muse, mutect2, varscan2
- NEK10 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1173001316, COSV55357096; called by muse, mutect2
- NPHS2 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs960225274; called by muse, mutect2
- OR4K13 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149397731; called by muse, mutect2, varscan2
- PCM1 | c.4382C>G p.P1461R | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767688104; called by muse, mutect2, varscan2
- PSMC6 | c.145G>T p.E49* (on ENST00000612399; = p.E35* on NM_002806.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV101471202, COSV71628905; called by mutect2, varscan2
- RNPC3 | c.1406C>G p.A469G | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166554367, COSV63716972; called by muse, varscan2
- SASH1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460340570, COSV66559266; called by muse, mutect2
- SCUBE1 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs373899025, COSV100683586; called by mutect2, varscan2
- SLC4A10 | c.3083C>T p.T1028M (on ENST00000446997 / NM_001354461.2; = p.T998M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1213730217; called by muse, mutect2, varscan2
- SLIT1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs143868163; called by muse, mutect2, varscan2
- SOS2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs779591050; called by muse, mutect2, varscan2
- SPAG4 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1255000957; called by muse, mutect2
- SPATA18 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764434785, COSV54643128; called by muse, mutect2, varscan2
- SRCAP | c.5303T>G p.L1768R | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV52681667; called by muse, mutect2, varscan2
- TEX44 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1380416171; called by muse, mutect2, varscan2
- ZFYVE9 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV99819290; called by muse, mutect2, varscan2
- ANKRD52 | c.2431C>A p.L811I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATP10B | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- CPA1 | c.1201A>C p.K401Q | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.6545T>C p.M2182T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ELOVL3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2
- FNDC1 | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- GHR | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRID2 | c.2344G>T p.D782Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNF4G | c.972G>T p.M324I (on ENST00000354370 / NM_001330561.2; = p.M371I on NM_004133.5) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IFIT5 | c.449A>T p.K150I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF10 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- IL17RC | c.1952T>G p.L651R (on ENST00000295981 / NM_153461.4; = p.L565R on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT16P2 | n.536C>A | Splice Region (SNP) | VAF 20/241 reads (8%) | called by muse, mutect2
- LPP | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- MID2 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MTUS1 | c.2959A>G p.T987A (on ENST00000262102 / NM_001363061.1; = p.T153A on NM_020749.4) | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYT1 | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NXNL2 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- PARP1 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PDLIM3 | c.166C>T p.P56S (on ENST00000284770 / NM_001257963.1; = p.P223S on NM_014476.6) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- POLE | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RICTOR | c.2206T>G p.L736V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SAMD9L | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- STAT5A | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TMED5 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- VWF | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- XBP1 | c.240_241del p.N80Kfs*17 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- ZBTB34 | c.465C>G p.S155R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ZNF347 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.495); called by muse, mutect2
- C11orf96 | c.1017C>G p.A339= (on ENST00000339446; = p.A26= on NM_001145033.2) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs964602085; called by muse, mutect2, varscan2
- CCDC105 | c.1011G>A p.A337= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs991022543; called by muse, mutect2, varscan2
- CSPP1 | c.1512C>T p.V504= (on ENST00000676605; = p.V463= on NM_024790.6) | Silent (SNP) | VAF 164/341 reads (48%) | called by muse, mutect2, varscan2
- FBRSL1 | c.1362C>T p.H454= | Silent (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- FMR1 | c.1440G>A p.G480= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- INPP5D | c.33C>A p.T11= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- LGALS13 | c.351G>A p.P117= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV55679959; called by muse, mutect2, varscan2
- MICAL3 | c.3333G>A p.S1111= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs536343609, COSV101490889; called by muse, mutect2, varscan2
- NADK | c.141G>T p.L47= | Silent (SNP) | VAF 32/82 reads (39%) | called by mutect2, varscan2
- NTN3 | c.1038C>T p.A346= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs759176016, COSV99565395; called by muse, mutect2, varscan2
- OR13D1 | c.462C>T p.H154= | Silent (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- PRPF40A | c.591C>T p.N197= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- RBM6 | c.1815G>A p.R605= | Silent (SNP) | VAF 72/231 reads (31%) | called by muse, mutect2, varscan2
- ZNF213 | c.822C>T p.P274= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV67727846; called by muse, mutect2, varscan2
- AC018521.7 | n.290G>T | RNA (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- AFAP1 | c.-3+140del | Intron (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- ARMCX4 | c.1038+730T>C | Intron (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- BHLHE22 | chr8:64576424 C>T | 5'Flank (SNP) | VAF 17/196 reads (9%) | catalogued as rs751924691; called by muse, mutect2
- FAM220BP | n.247G>T | RNA (SNP) | VAF 22/125 reads (18%) | catalogued as rs1170273903; called by muse, mutect2, varscan2
- KATNBL1 | c.883-604T>C | Intron (SNP) | VAF 6/87 reads (7%) | catalogued as rs1353240239; called by muse, mutect2
- MGAT4EP | n.1460C>T | RNA (SNP) | VAF 22/182 reads (12%) | catalogued as rs752777675; called by muse, mutect2, varscan2
- MMP26 | c.-145+92794G>A | Intron (SNP) | VAF 3/35 reads (9%) | catalogued as rs1347631260; called by muse, mutect2
- RAPGEF6 | c.*86G>C | 3'UTR (SNP) | VAF 11/115 reads (10%) | catalogued as COSV57256575; called by muse, mutect2, varscan2
- TTC3P1 | n.5023G>C | RNA (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
